Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0FV, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0FV-01A (Primary Tumor).

TSS Patient ID:

Case #: DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: **Breast Cancer** Histological description: **Infiltrative ductal carcinoma**

Date of Procurement: Anatomic Site: **Right Breast** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **Frozen**

Container: **cryomold** Type of Procurement: **Radical mastectomy** Grade: **2**

T Stage: **2** N Stage: **0** M Stage: **0** Treatment: **none**

Treatment Details: **n/a**

Normal Sample

Anatomic Site: **Blood** Sample Type: **Normal** Type of Procurement: **blood draw**

Matrix: **Blood** Specimen Format: **frozen** Container: **tube**

Date of Procurement:

ICD-0-3

carcinoma, infiltrating duct, NOS 8500/3

Site: breast, NOS C50.9 bw 10/21/11

1PAA Discrepancy		☒

bw 10/21/11

Source: NCI Genomic Data Commons file d55d9ed9-3663-4538-89e8-0d80e55cc678 (TCGA-AN-A0FV.5AEE90E0-A9A1-4944-AD6A-2675764D869D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).